Gene-level copy-number profile of tumor specimen REBC-ACAH-TTP1-A from REBC case REBC-ACAH, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACAH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a6be8123-fe4c-4da9-bf5c-e9a636be6b64.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACAH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/099418f8-6a48-4377-9276-5b1668a95d59

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 441; copy number 2: 57,807; copy number 3: 16; copy number 4: 109; copy number 5: 13; copy number 6: 6.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:197,569–209,892, 1 gene, copy number 6: AC079779.1.
- chr5:174,724,582–174,730,896, 1 gene, copy number 5: MSX2.
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,257,879–38,329,643, 11 genes, copy number 5: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2.
- chr21:44,350,163–44,455,284, 5 genes, copy number 6: TRPM2, TRPM2-AS, AP001065.2, AP001065.1, LRRC3-DT.

Autosomal genes at a single copy (total copy number 1): 441. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
